Somatic mutation profile of tumor specimen 0DQJIY from CCDI case PBCEYL, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Ventricle, NOS; Age at diagnosis: 8.3 years (3,043 days).
Specimen 0DQJIY: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 05532448-0901-4bb5-9f86-a820a447d730.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DQJIJ (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/884adadb-9df3-4a31-bf24-af7155ad9e8c

The open-access MAF lists 27 somatic variants for this specimen: 16 protein-altering or splice-affecting, 6 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 6, Intron 4, Frame Shift Ins 1, Nonsense Mutation 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C4orf47 | c.425A>G p.Y142C | Missense Mutation (SNP) | VAF 28/803 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as rs974316000; called by muse, mutect2
- CCDC73 | c.1341dup p.E448Rfs*12 | Frame Shift Ins (INS) | VAF 102/124 reads (82%) | catalogued as rs747079826; called by mutect2, varscan2
- FAM3D | c.109C>T p.P37S | Missense Mutation (SNP) | VAF 228/510 reads (45%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.724); catalogued as COSV62558574, COSV62559026; called by muse, mutect2, varscan2
- MUC17 | c.229G>A p.V77M | Missense Mutation (SNP) | VAF 243/881 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.072); catalogued as rs777479634, COSV60283635; called by muse, mutect2, varscan2
- TMC5 | c.509C>G p.S170C | Missense Mutation (SNP) | VAF 32/1073 reads (3%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.436); catalogued as COSV66868410; called by muse, mutect2
- USP5 | c.1529G>A p.R510Q | Missense Mutation (SNP) | VAF 22/691 reads (3%) | SIFT tolerated (0.33); PolyPhen benign (0.329); catalogued as rs781936322; called by muse, mutect2
- ZNF831 | c.3618C>G p.Y1206* | Nonsense Mutation (SNP) | VAF 25/600 reads (4%) | catalogued as COSV100925693; called by muse, mutect2
- CPNE1 | c.244G>A p.D82N (on ENST00000352393; = p.D87N on NM_003915.5) | Missense Mutation (SNP) | VAF 30/952 reads (3%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); called by muse, mutect2
- HINFP | c.1387G>T p.V463F | Missense Mutation (SNP) | VAF 10/180 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.051); called by muse, mutect2
- HSPA12B | c.1382T>C p.V461A | Missense Mutation (SNP) | VAF 186/206 reads (90%) | SIFT deleterious (0.02); PolyPhen benign (0.356); called by muse, mutect2, varscan2
- ITPR1 | c.7869C>G p.N2623K (on ENST00000354582; = p.N2568K on NM_002222.7) | Missense Mutation (SNP) | VAF 313/734 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- LYL1 | c.718G>C p.G240R | Missense Mutation (SNP) | VAF 190/420 reads (45%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- OMD | c.161C>T p.P54L | Missense Mutation (SNP) | VAF 123/793 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR2T12 | c.763T>A p.F255I | Missense Mutation (SNP) | VAF 951/1775 reads (54%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- PGAP3 | c.338T>C p.L113P | Missense Mutation (SNP) | VAF 290/705 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SCN7A | c.4672C>A p.Q1558K | Missense Mutation (SNP) | VAF 52/1048 reads (5%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.889); called by muse, mutect2
- ABCC3 | c.1422C>T p.R474= | Silent (SNP) | VAF 184/729 reads (25%) | catalogued as rs145605804; called by muse, mutect2, varscan2
- ALOXE3 | c.381C>T p.P127= | Silent (SNP) | VAF 317/708 reads (45%) | catalogued as rs754375921; called by muse, mutect2, varscan2
- CTDP1 | c.1662G>A p.A554= | Silent (SNP) | VAF 243/524 reads (46%) | catalogued as rs200457218; called by muse, mutect2, varscan2
- SERPINB3 | c.1170G>T p.P390= | Silent (SNP) | VAF 231/578 reads (40%) | called by muse, mutect2, varscan2
- TAS2R16 | c.858T>A p.I286= | Silent (SNP) | VAF 329/1190 reads (28%) | called by muse, mutect2, varscan2
- VPS33A | c.363C>T p.C121= | Silent (SNP) | VAF 340/834 reads (41%) | catalogued as rs141508284; called by muse, mutect2, varscan2
- BEX3 | c.*8_*9dup | 3'UTR (INS) | VAF 76/226 reads (34%) | called by mutect2, pindel, varscan2
- CAPS | c.-22-33G>A | Intron (SNP) | VAF 133/436 reads (31%) | catalogued as rs751449351; called by muse, mutect2, varscan2
- FMN1 | c.2044-2530A>G | Intron (SNP) | VAF 37/972 reads (4%) | called by muse, mutect2
- NDRG1 | c.99+53T>C | Intron (SNP) | VAF 26/838 reads (3%) | called by muse, mutect2
- SLC11A2 | c.270+76A>T | Intron (SNP) | VAF 87/216 reads (40%) | called by muse, mutect2, varscan2
